Surgical pathology report (de-identified scan), TCGA case TCGA-ZC-AAAA, project TCGA-THYM (Thymoma), tissue source site  University of Mannheim, specimen TCGA-ZC-AAAA-01A (Primary Tumor).

Original report (translation):

Macroscopy:

Thank you for sending this 9.8x7.5x4.2cm mediastinal resection with soft tissue at two sides, thymic tissue and with a blurred and incomplete capsule-limited tumor of 6cm diameter in the middle. Obviously dorsally 7.5x5.5cm of pericardium. Delineated within the adipose tissue, small lymph nodes.

Microscopy:

Histologically, an unusual finding of an invasively growing WHO type B2 thymoma that grows invasively into the mediastinal fat tissue. A distinct capsule is only ventrally and dorsally visible, so that an invasion depth of over 3 mm is expectable (stage IIB). At one of the narrow sides, tumour strands approach up to the coagulated surface, so that the tumour is not removed in the healthy. The other surgical margins are free of tumour. Noteworthy, there are marked cystic changes. Only a small portion of these cysts is within the tumour. The vast majority is related to the pronounced atrophic thymic rests, which forms a multilocular thymic cyste. The thymus is highly atrophic with respect to the thymic cortex. Significant activation of lymph node. In addition, detection of ectopic parathyroid gland.

Assessment:

This is an invasive WHO type B2 thymoma with invasion into the mediastinal adipose tissue but not growing into the pericardium. The tumour extends to the ventro-lateral right coagulated surface, so that an R0 resection can not be diagnosed. The remaining resection borders are tumour free. Furthermore, a pronounced thymitis (grade 3) with the same high-grade accidental involution and formation of a broad multilocular thymic cyst. Activated, tumour-free mediastinal lymph nodes and heterotopic parathyroid tissue. No evidence of a thymic carcinoma.

Tumor stage according to Masaoka-Koga/ITMIG: IIB

Resection: R1 (ventrolateral in an approximately 1mm wide range

Short report:

Date of tumour procurement:

Anatomic site:

Mediastinum

Final diagnosis:

WHO-type B2

Discrepancy between histology on frozen section and paraffin section:

None

ICD O-3
Thymoma, type B2, malignant
G1E 8584/3
Site Anterior mediastinum C38.1
path
Mediastinum NOS C38.3
W 3/12/14

Source: NCI Genomic Data Commons file 0833143c-21eb-444f-9a05-d1d353e8d075 (TCGA-ZC-AAAA.EC05EFA3-AFAB-47BE-AC15-6477CA4BCAF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).